Somatic mutation profile of tumor specimen RC-B5DB-TBP1-A (aliquot RC-B5DB-TBP1-A-1-0-D-A93N-47) from RC case RC-B5DB, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,902 days).
Specimen RC-B5DB-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5ee167d-6a7d-473a-b76b-7a4d1b27d03e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5DB-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5DB-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7724315-0bf6-4938-84e0-840374b8476e

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNK9 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57280170; called by muse, mutect2
- SEMA6B | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1193261247; called by muse, mutect2
- APOB | c.3010del p.E1004Nfs*2 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- C3orf62 | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- CDH19 | c.1387A>T p.I463F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- POTEI | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by mutect2, varscan2
- SLC44A5 | c.1552T>A p.F518I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- FLG2 | c.5325C>T p.G1775= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as rs759778011, COSV66170893; called by muse, mutect2
